Somatic mutation profile of tumor specimen TCGA-DQ-5631-01A (aliquot TCGA-DQ-5631-01A-01D-1870-08) from TCGA case TCGA-DQ-5631, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G3; Age at diagnosis: 52.5 years (19,172 days).
Specimen TCGA-DQ-5631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c49249bd-7add-4afb-9575-b51055e4ac34.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DQ-5631-10A (Blood Derived Normal), aliquot TCGA-DQ-5631-10A-01D-1870-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d513566-7e4c-4b39-ab51-f46751f128a8

The open-access MAF lists 100 somatic variants for this specimen: 72 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 26, Nonsense Mutation 7, Frame Shift Del 3, Splice Site 2, 5'UTR 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.4879C>T p.R1627* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | hotspot (GDC flag); catalogued as rs1340793072, COSV71673166; called by muse, mutect2, varscan2
- NOTCH1 | c.1318T>C p.C440R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025387, COSV53107289; called by muse, mutect2, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC024598.1 | c.1207C>T p.Q403* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100760315; called by muse, mutect2, varscan2
- ADAMTS3 | c.3479C>T p.S1160L | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1341858344, COSV99710504; called by muse, mutect2
- AMDHD2 | c.417G>T p.G139= | Splice Region (SNP) | VAF 8/23 reads (35%) | catalogued as rs1377930050, COSV99565696; called by muse, mutect2, varscan2
- AP2A1 | c.2831G>A p.R944Q | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1283254918, COSV100571042; called by muse, mutect2, varscan2
- ARSF | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 22/36 reads (61%) | catalogued as COSV63840200; called by muse, mutect2, varscan2
- AURKB | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100298656; called by muse, mutect2, varscan2
- BCOR | c.449A>G p.K150R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100653035; called by muse, mutect2, varscan2
- CACNG8 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99554897; called by muse, mutect2, varscan2
- CCDC138 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV99718907; called by muse, mutect2, varscan2
- CCP110 | c.2210C>G p.S737* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as COSV101195236, COSV66816968; called by muse, mutect2, varscan2
- CDH19 | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV100051162; called by muse, mutect2, varscan2
- CSMD1 | c.8020A>T p.T2674S (on ENST00000520002; = p.T2673S on NM_033225.6) | Missense Mutation (SNP) | VAF 118/216 reads (55%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.468); catalogued as COSV100145295; called by muse, mutect2, varscan2
- CT55 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1201632896, COSV52277629; called by muse, mutect2, varscan2
- CTC1 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as COSV100236241; called by muse, mutect2, varscan2
- DAB2 | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs374766869; called by muse, mutect2, varscan2
- DACH1 | c.1834C>T p.P612S (on ENST00000619232 / NM_001366712.1; = p.P358S on NM_004392.6) | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV57490296; called by muse, mutect2
- DEFB124 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (1); catalogued as COSV100478744; called by muse, mutect2, varscan2
- DNAAF1 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs376980896; called by muse, mutect2, varscan2
- DNAJC10 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 43/224 reads (19%) | catalogued as COSV99899003; called by muse, mutect2, varscan2
- DST | c.21508G>A p.E7170K (on ENST00000361203 / NM_001374722.1; = p.E4867K on NM_015548.5) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1229104808, COSV99751385; called by muse, mutect2, varscan2
- EFHC1 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100931915; called by muse, mutect2, varscan2
- EPPK1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.425); catalogued as rs782482896; called by muse, mutect2
- FBXW10 | c.1232+1G>A p.X411_splice | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as rs542471358, COSV57316846; called by muse, mutect2, varscan2
- FGA | c.1052G>T p.S351I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV100120170, COSV100120958; called by muse, mutect2, varscan2
- FOXI1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377532550; called by muse, mutect2, varscan2
- GABRG1 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.334); catalogued as COSV54956622, COSV99777603; called by muse, mutect2, varscan2
- GLRX2 | c.137C>T p.S46L (on ENST00000367439 / NM_197962.3; = p.S47L on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100814162; called by muse, mutect2, varscan2
- HEATR3 | c.1994G>A p.R665Q | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); catalogued as rs137897639; called by muse, mutect2, varscan2
- HRNR | c.3146G>C p.G1049A | Missense Mutation (SNP) | VAF 62/391 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs1293731425, COSV100913120, COSV100913279; called by muse, mutect2, varscan2
- ITGA2B | c.2930G>T p.R977L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as CD021198, CD061427, COSV52235917, COSV99288665; called by muse, mutect2, varscan2
- JAKMIP1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV51547166; called by muse, mutect2, varscan2
- KIF2B | c.1651C>A p.H551N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99274921; called by muse, mutect2, varscan2
- LILRA1 | c.571C>T p.R191C | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs141328341; called by muse, mutect2, varscan2
- LRRC8A | c.1048A>C p.K350Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99396367; called by muse, mutect2, varscan2
- MKRN1 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.711); catalogued as COSV99751508; called by muse, mutect2, varscan2
- MRGPRX4 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100049670; called by muse, mutect2, varscan2
- MYH13 | c.1311G>A p.M437I | Missense Mutation (SNP) | VAF 38/176 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV99352893; called by muse, mutect2, varscan2
- NANS | c.870+1G>T p.X290_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV99271113; called by muse, mutect2, varscan2
- NEB | c.2607C>G p.H869Q | Missense Mutation (SNP) | VAF 50/216 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99417398; called by muse, mutect2, varscan2
- NLRP3 | c.788G>T p.S263I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100275558; called by muse, mutect2, varscan2
- OLFML1 | c.539G>C p.G180A | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100206025, COSV100206222; called by muse, mutect2, varscan2
- PCDH11X | c.173C>A p.T58K | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100009611; called by muse, mutect2, varscan2
- PCDHGA4 | c.1403A>T p.H468L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV99533573; called by muse, mutect2, varscan2
- PDE8B | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99366381; called by muse, mutect2, varscan2
- PPP1R32 | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs766852224, COSV58544722; called by muse, mutect2, varscan2
- PPP2R1B | c.581G>C p.R194P | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100231972; called by muse, mutect2, varscan2
- RBM7 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs376690569, COSV100348306; called by muse, mutect2, varscan2
- RPGRIP1 | c.2813C>A p.P938Q | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.642); catalogued as COSV99250645; called by muse, mutect2, varscan2
- RYR2 | c.2693T>C p.I898T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63702172; called by muse, mutect2, varscan2
- SIGLEC6 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776953751, COSV100585224, COSV58438093; called by muse, mutect2, varscan2
- SLC12A5 | c.2407C>T p.R803C (on ENST00000454036 / NM_001134771.2; = p.R780C on NM_020708.5) | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs757395459, COSV54788236; called by muse, mutect2, varscan2
- SMG8 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.982); catalogued as COSV56285626; called by muse, mutect2, varscan2
- SOS2 | c.3787C>G p.P1263A | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV53566572, COSV99365599; called by muse, mutect2, varscan2
- STAT3 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.149); catalogued as COSV99232563; called by muse, mutect2, varscan2
- THADA | c.940A>C p.T314P | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.296); catalogued as COSV100368148; called by muse, mutect2, varscan2
- TP53 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 6/43 reads (14%) | catalogued as CM044725, COSV52746809, COSV52814837, COSV53366474; called by muse, mutect2, varscan2
- TRIM5 | c.650C>G p.S217C | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs140632799; called by muse, mutect2, varscan2
- TSSK6 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.086); catalogued as rs1027241107, COSV99388859; called by muse, mutect2, varscan2
- TTC27 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as rs776673745, COSV100512789, COSV58650314; called by muse, mutect2, varscan2
- USP35 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.838); catalogued as COSV101489059; called by muse, mutect2, varscan2
- WDR7 | c.2278G>C p.D760H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV99588928; called by muse, mutect2, varscan2
- WDR88 | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 24/103 reads (23%) | catalogued as rs746514517, COSV63450709; called by muse, mutect2, varscan2
- WNT9A | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.605); catalogued as rs756226986, COSV99688092; called by muse, mutect2, varscan2
- ZNF496 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs766322731, COSV99665397; called by muse, mutect2, varscan2
- ZNF707 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as COSV100690544; called by muse, mutect2, varscan2
- ASXL1 | c.1696del p.E566Sfs*137 | Frame Shift Del (DEL) | VAF 24/135 reads (18%) | called by mutect2, pindel, varscan2
- ENO3 | c.240+1del | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- MYH13 | c.4630C>A p.L1544M | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.292); called by muse, mutect2
- NOTCH2 | c.478_482del p.T160Cfs*19 | Frame Shift Del (DEL) | VAF 20/135 reads (15%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.558C>T p.S186= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs757230093, COSV53183618; called by mutect2, varscan2
- BLOC1S2 | c.66C>G p.A22= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs775898626, COSV58397724; called by muse, mutect2, varscan2
- CACNA1G | c.4644G>A p.E1548= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as rs1356430135, COSV100661383; called by muse, mutect2, varscan2
- CERKL | c.789C>T p.S263= (on ENST00000339098 / NM_001030311.2; = p.S237= on NM_201548.5) | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV59205492; called by muse, mutect2, varscan2
- COL11A1 | c.2739C>T p.G913= | Silent (SNP) | VAF 31/213 reads (15%) | catalogued as rs1553224335, COSV100615531; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAJC1 | c.1176G>A p.S392= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs148336959; called by muse, mutect2, varscan2
- ERBB3 | c.3225T>C p.S1075= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV57246677, COSV99916166; called by muse, mutect2, varscan2
- FCGR3B | c.333C>G p.L111= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV54211158, COSV99670440; called by muse, mutect2, varscan2
- GSKIP | c.342C>G p.L114= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as COSV101347612; called by muse, mutect2, varscan2
- GTPBP4 | c.699G>A p.R233= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs138136568; called by muse, mutect2
- H2BC11 | c.201G>A p.V67= | Silent (SNP) | VAF 57/226 reads (25%) | catalogued as COSV60362427; called by muse, mutect2, varscan2
- ITGB4 | c.4038C>T p.F1346= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as COSV99563606; called by muse, mutect2, varscan2
- MAP2 | c.3435G>A p.L1145= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99558639; called by muse, mutect2, varscan2
- MAP7D2 | c.159G>A p.E53= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV101107233; called by muse, mutect2, varscan2
- MUC16 | c.26556T>C p.P8852= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as COSV101198799; called by muse, mutect2, varscan2
- MUC17 | c.9924C>A p.T3308= | Silent (SNP) | VAF 173/616 reads (28%) | catalogued as COSV100072255; called by muse, mutect2, varscan2
- MYH4 | c.1074C>T p.A358= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV99700626; called by muse, mutect2, varscan2
- NLRP7 | c.1242G>A p.T414= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs751935141, COSV60173764; called by muse, mutect2
- PIDD1 | c.556C>T p.L186= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs757920453, COSV100758542; called by muse, mutect2, varscan2
- PRKX | c.480C>T p.I160= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs773442758, COSV53323133; called by muse, mutect2, varscan2
- RSF1 | c.3768G>A p.K1256= | Silent (SNP) | VAF 11/158 reads (7%) | catalogued as COSV100406974; called by muse, mutect2
- SCRIB | c.1251C>T p.P417= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs1344101145, COSV100252797; called by mutect2, varscan2
- SLC25A20 | c.213A>G p.L71= | Silent (SNP) | VAF 35/96 reads (36%) | catalogued as rs928258340, COSV100033640; called by muse, mutect2, varscan2
- SOS2 | c.1281C>T p.I427= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs8010578, COSV99365397; called by muse, mutect2, varscan2
- STX1A | c.639C>T p.H213= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs781896614, COSV56096728; called by muse, mutect2, varscan2
- ZNF761 | c.1608C>T p.S536= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV100483299; called by muse, mutect2, varscan2
- ANKRD33 | c.-144C>A | 5'UTR (SNP) | VAF 15/104 reads (14%) | catalogued as rs1349550933, COSV100001161; called by muse, mutect2, varscan2
- DUOXA1 | chr15:45118067 G>A | 3'Flank (SNP) | VAF 4/27 reads (15%) | catalogued as COSV99972962; called by muse, mutect2
